Somatic mutation profile of tumor specimen MBCProject_1353_T3_WES (aliquot MBCProject_1353_T3_WES_1) from CMI case MBCProject_1353, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.9 years (13,832 days).
Specimen MBCProject_1353_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb6b6cd6-5ac8-41de-8f1e-486ef5f8d66b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1353_SALIVA (Saliva), aliquot MBCProject_1353_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5238e8b-19b5-4451-9c11-7dd53846b9f1

The open-access MAF lists 35 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 11, Silent 6, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1610A>C p.Y537S | Missense Mutation (SNP) | VAF 20/348 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52782924, COSV52783938; called by muse, mutect2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD52 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs1381126304; called by mutect2, varscan2
- CDH5 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs375308404; called by muse, mutect2, varscan2
- DNM1 | c.589+1G>T p.X197_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV57853309; called by muse, mutect2
- KIF14 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV66262313; called by muse, mutect2, varscan2
- LTBP3 | c.2769C>G p.F923L | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV99534490; called by muse, mutect2, varscan2
- RELB | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV55513454; called by muse, mutect2
- ZNF704 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as rs192436127; called by muse, mutect2, varscan2
- DCAF8L1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FUT9 | c.407T>C p.L136S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NEB | c.10377del p.D3459Efs*16 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- PPP6R3 | c.1753G>C p.D585H (on ENST00000393800 / NM_001352375.2; = p.D505H on NM_018312.5) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLC49A4 | c.1282A>T p.M428L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by mutect2, varscan2
- SPTLC1 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TGFBR3 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH5 | c.13224C>T p.R4408= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV99456492; called by muse, mutect2, varscan2
- FIGN | c.288A>T p.S96= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- HELQ | c.96C>G p.A32= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as rs1218776448; called by muse, mutect2
- PTPRS | c.3108G>T p.S1036= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs201545244; called by mutect2, varscan2
- RFXANK | c.66G>A p.G22= | Silent (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- TFE3 | c.1116C>A p.L372= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV59946560; called by muse, mutect2, varscan2
- ADGRD1 | c.2109-22A>G | Intron (SNP) | VAF 39/268 reads (15%) | called by muse, mutect2, varscan2
- ANKS1B | c.2886+83G>A | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs765772439; called by mutect2, varscan2
- ARMCX4 | c.1038+3731C>T | Intron (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- DDX3X | c.1022+115C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs748781701; called by mutect2, varscan2
- FAM118A | c.522+369T>G | Intron (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5319C>T | Intron (SNP) | VAF 33/364 reads (9%) | called by muse, mutect2
- KCNQ1 | c.*481C>T | 3'UTR (SNP) | VAF 15/71 reads (21%) | catalogued as rs754424379; called by muse, mutect2, varscan2
- MBD3 | c.*2898A>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- SLC11A2 | c.1165-27C>G | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, varscan2
- SLC6A8 | c.1254+41G>A | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as rs782294985; called by mutect2, varscan2
- SNX29 | c.247+2193T>G | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, varscan2
- UPK1A | c.648+241A>G | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as rs1467100085; called by mutect2, varscan2
